CCDI case PBCAEL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/425b1fb1-9c3f-4c6d-8ce2-976aebbd0ce6

Demographics
Sex at birth: female.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 3.0 years (1,108 days).

Biospecimens (3 samples)
- Sample 0DM8U7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DM8UE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DM8VZ: Tissue type: Tumor; Specimen type: Solid Tissue.
